Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A2LX, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A2LX-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

DOB:

Accession

Surgical Pathology Report

Final

al Pathology

SURGICAL PATHOLOGY REPORT FINAL

Patient Name:

Address

Gender: F

DOB

Service:Obstetrics

Location

MRN

Hospital

Patient Type:

Accession #

Taken

Received

Accessioned

Reported

Physician(s):

M.D.

Other Related Clinical Data:

DIAGNOSIS:

UTERUS, CERVIX, BIOPSY

- MODERATELY DIFFERENTIATED INVASIVE SQUAMOUS CELL CARCINOMA

ICD-0-3
carcinoma, squamous cell 8070/3
Site: cervix, NOS C53.9

8/18/11

By this signature, I attest that the above diagnosis is
based upon my personal
examination of the slides (and/or other material indicated in the
diagnosis).

M.D.

***Report Electronically Reviewed and Signed Out By

M.D.***

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

History:

The patient is year old woman with a last menses in operative
procedure: Cervical biopsy.

Specimen(s) Received:

A: CERVIX

Gross Description

The specimen is received in one formalin-filled container labeled "
" and "cervical biopsy." It holds multiple fragments of tan tissue that range
from 0.2 to 0.4 cm. Labeled #1 to 10.

The performance characteristics of some immunohistochemical stains, fluorescence
in-situ hybridization tests and immunophenotyping by flow cytometry cited in
this report (if any) were determined by the

as part of an ongoing quality assurance program and in
compliance with federally mandated regulations drawn from the Clinical
Laboratory Improvement Act of 1988 (CLIA '88). Some of these tests rely on the

[page 2 of 2]
Patient Name:

DOB:

Accession:

MRN:

PAN:

use of "analyte specific reagents" and are subject to specific labeling requirements by the US Food and Drug Administration. Such diagnostic tests may only be performed in a facility that is certified by the Department of Health and Human Services as a high complexity laboratory under CLIA '88. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. Nevertheless, federal rules concerning the medical use of analyte specific reagents require that the following disclaimer be attached to the report:

This test was developed and its performance characteristics determined by the . It has not been cleared or approved by the U. S. Food and Drug Administration.

Source: NCI Genomic Data Commons file 2ead5369-a71e-4181-ab61-42236279cbfd (TCGA-C5-A2LX.CF12FC3E-41CA-48EE-AF88-15ACA2C0067D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).